Somatic mutation profile of tumor specimen TCGA-AA-A01P-01A (aliquot TCGA-AA-A01P-01A-21D-A17O-10) from TCGA case TCGA-AA-A01P, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage III; Age at diagnosis: 80.9 years (29,554 days).
Specimen TCGA-AA-A01P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13517a71-e273-479c-ab32-79d17057d20b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01P-11A (Solid Tissue Normal), aliquot TCGA-AA-A01P-11A-11D-A17O-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcab959a-f121-4798-bae2-0d014aacc806

The open-access MAF lists 1,059 somatic variants for this specimen: 809 protein-altering or splice-affecting, 231 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 553, Silent 231, Frame Shift Del 163, Frame Shift Ins 32, Nonsense Mutation 25, Splice Site 14, Intron 10, In Frame Del 10, Splice Region 9, RNA 5, 3'UTR 4, In Frame Ins 3.

Variants (750 of 1,059; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMELX | c.499del p.L167Cfs*8 | Frame Shift Del (DEL) | VAF 43/219 reads (20%) | catalogued as rs387906490; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BMPR1A | c.176del p.L59* | Frame Shift Del (DEL) | VAF 36/170 reads (21%) | catalogued as rs786201038; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FKRP | c.1141del p.A381Qfs*47 | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | catalogued as rs754403441; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- GRIN2A | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397518468, CM138212, COSV58031541; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- NPC1 | c.2978del p.G993Efs*4 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs775915490, CD053590, COSV99342140; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NPC1 | c.631+2T>C p.X211_splice | Splice Site (SNP) | VAF 26/80 reads (33%) | catalogued as rs1555638833, COSV99341263; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2361dup p.T788Hfs*5 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | catalogued as rs770591449; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 14/66 reads (21%) | hotspot (GDC flag); called by pindel, varscan2
- RHOA | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 38/186 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69041545, COSV69041670; called by muse, mutect2, varscan2
- TJP2 | c.2438del p.F813Sfs*12 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | catalogued as rs776869985; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TRMT1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542184779, COSV99679013; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs766775847, COSV100068403; called by muse, mutect2, varscan2
- ABCC1 | c.3332C>A p.A1111D | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100579451; called by muse, mutect2, varscan2
- AC098582.1 | c.1679T>C p.V560A | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV99985542; called by muse, mutect2, varscan2
- ACADSB | c.594T>A p.Y198* | Nonsense Mutation (SNP) | VAF 16/121 reads (13%) | catalogued as COSV100715180; called by muse, mutect2, varscan2
- ACAN | c.1097del p.G366Vfs*10 | Frame Shift Del (DEL) | VAF 27/106 reads (25%) | catalogued as COSV61366998; called by mutect2, pindel, varscan2
- ACBD4 | c.639+2T>C p.X213_splice (on ENST00000376955 / NM_001378111.1; = p.X217_splice on NM_024722.4) | Splice Site (SNP) | VAF 24/106 reads (23%) | catalogued as COSV100416176; called by muse, mutect2, varscan2
- ACE2 | c.971C>G p.T324S | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as COSV99382759; called by muse, mutect2, varscan2
- ACTG2 | c.85del p.R29Gfs*16 | Frame Shift Del (DEL) | VAF 21/91 reads (23%) | catalogued as rs751325833; called by mutect2, pindel, varscan2
- ADAM11 | c.2204T>C p.I735T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99567433; called by muse, mutect2, varscan2
- ADAMTS19 | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50732749, COSV50746318; called by muse, mutect2, varscan2
- ADAMTS5 | c.2440A>G p.R814G | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.341); catalogued as COSV99537530; called by muse, mutect2, varscan2
- ADAMTSL2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1001640157, COSV100618958; called by muse, mutect2
- ADGRG3 | c.799A>T p.I267F | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as COSV100342350; called by muse, mutect2, varscan2
- ADPRHL1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs563174718, COSV62910319; called by muse, mutect2, varscan2
- AFF3 | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs771583669, COSV100418731; called by muse, mutect2, varscan2
- AFM | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs199782653, COSV56919520; called by muse, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | catalogued as rs779815391; called by mutect2, varscan2
- AKAP12 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99483091; called by muse, mutect2, varscan2
- AL669918.1 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV101441043; called by muse, mutect2, varscan2
- ALK | c.4436C>T p.A1479V | Missense Mutation (SNP) | VAF 25/344 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as rs1558603789, COSV101201909, COSV66560749; ClinVar: uncertain significance; called by muse, mutect2
- ALMS1 | c.2767C>T p.P923S | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100042269; called by muse, mutect2
- ALOX12 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52352835; called by muse, mutect2, varscan2
- AMELX | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 66/336 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100497946; called by mutect2, varscan2
- AMHR2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as rs757117832, COSV99143182; called by muse, mutect2, varscan2
- AMOT | c.2525C>A p.S842* (on ENST00000371959 / NM_001113490.1; = p.S433* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100494995, COSV100495007; called by muse, mutect2, varscan2
- ANGPTL2 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs935179408, COSV99401540; called by muse, mutect2, varscan2
- ANGPTL6 | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99463604; called by muse, mutect2, varscan2
- ANK1 | c.2512G>A p.D838N | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55892464; called by muse, mutect2, varscan2
- ANK2 | c.5275G>A p.E1759K | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100001408; called by muse, mutect2, varscan2
- ANK3 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55086348; called by muse, mutect2, varscan2
- ANKFY1 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1177246007, COSV58920284; called by muse, mutect2, varscan2
- ANKRD13A | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1373075190, COSV99923958; called by muse, mutect2, varscan2
- ANKRD34A | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60162236; called by muse, mutect2, varscan2
- ANKRD50 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV101538945; called by muse, mutect2, varscan2
- ANKRD53 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1006652499, COSV99721351; called by muse, mutect2, varscan2
- ANKS1B | c.2329A>G p.T777A | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.956); catalogued as COSV100245248; called by mutect2, varscan2
- ANO4 | c.1441C>T p.R481W (on ENST00000392977 / NM_001286615.2; = p.R446W on NM_178826.4) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs765804915, COSV54602170; called by muse, mutect2, varscan2
- ANTXR2 | c.1123A>C p.T375P | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56320622; called by muse, mutect2, varscan2
- AP1G2 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs200202756; called by muse, mutect2, varscan2
- AP1M2 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV99140815; called by muse, mutect2, varscan2
- AP2A1 | c.2845G>T p.A949S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.098); catalogued as COSV100571126; called by muse, mutect2
- APBB2 | c.2140C>T p.P714S (on ENST00000295974 / NM_001166050.2; = p.P715S on NM_004307.2) | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV99922951; called by muse, mutect2, varscan2
- APOA4 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs549843769, COSV100759315; called by muse, mutect2, varscan2
- APOB | c.4250C>T p.T1417M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.147); catalogued as rs200321839, COSV51928643; called by muse, mutect2, varscan2
- AR | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as rs763968978, COSV65964845; called by muse, mutect2, varscan2
- ARFIP1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs145188297; called by muse, mutect2, varscan2
- ARHGAP33 | c.2561C>T p.A854V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99138121; called by muse, mutect2, varscan2
- ARHGAP39 | c.1095del p.S366Rfs*18 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs751388541; called by mutect2, pindel, varscan2
- ARHGAP45 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1330958470, COSV100490654; called by muse, mutect2, varscan2
- ARHGEF10 | c.2878A>G p.M960V (on ENST00000398564; = p.M935V on NM_014629.4) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100034438; called by muse, mutect2, varscan2
- ARHGEF17 | c.3059C>T p.P1020L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); catalogued as COSV55232073, COSV99735492; called by muse, mutect2, varscan2
- ARHGEF4 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV100388015; called by muse, varscan2
- ARHGEF40 | c.1891C>A p.L631I | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100070295; called by muse, mutect2, varscan2
- ARID1B | c.6595C>T p.R2199C | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs371461578; called by muse, mutect2, varscan2
- ARL8B | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99848618; called by muse, mutect2, varscan2
- ARMC10 | c.962T>C p.I321T | Missense Mutation (SNP) | VAF 38/397 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs1448565653, COSV58524390; called by muse, mutect2, varscan2
- ARNT2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211454281, COSV100308950; called by muse, mutect2, varscan2
- ARSD | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs776244005, COSV54203967; called by muse, mutect2, varscan2
- ASH1L | c.7582C>T p.R2528C (on ENST00000368346 / NM_001366177.2; = p.R2523C on NM_018489.3) | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs1376913986, COSV64208707; called by muse, mutect2, varscan2
- ATAD3A | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 82/331 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs540171241, COSV59236610; called by muse, mutect2, varscan2
- ATAD5 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1004100672, COSV58974436; called by muse, mutect2, varscan2
- ATP4A | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV99382523; called by muse, mutect2, varscan2
- ATXN1 | c.1111A>G p.S371G | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99786220; called by muse, mutect2, varscan2
- ATXN2L | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs560637561, COSV100294253; called by muse, mutect2, varscan2
- AXIN2 | c.2011del p.R671Afs*18 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | catalogued as COSV61055329; called by mutect2, pindel, varscan2
- AXIN2 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs367938045; ClinVar: uncertain significance; called by muse, mutect2
- B4GALT5 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100866994; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 33/91 reads (36%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEND3 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.32); catalogued as rs781792938, COSV100944597; called by muse, mutect2, varscan2
- BFAR | c.763dup p.Q255Pfs*7 | Frame Shift Ins (INS) | VAF 11/47 reads (23%) | catalogued as rs781267226; called by mutect2, varscan2
- BICRA | c.2810dup p.P938Tfs*127 | Frame Shift Ins (INS) | VAF 26/166 reads (16%) | catalogued as rs755506199; called by mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNC2 | c.1428C>A p.C476* | Nonsense Mutation (SNP) | VAF 40/213 reads (19%) | catalogued as COSV101033083; called by muse, mutect2, varscan2
- BPIFB6 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.305); catalogued as COSV100848511; called by muse, mutect2, varscan2
- BRINP3 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs763233124, COSV66534847; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 26/156 reads (17%) | catalogued as rs1455506786, COSV59000653; called by mutect2, varscan2
- BRWD3 | c.1283T>C p.M428T | Missense Mutation (SNP) | VAF 110/552 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV100955982; called by muse, mutect2, varscan2
- BTBD1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.196); catalogued as COSV99915451; called by muse, mutect2, varscan2
- BUB1 | c.1856T>C p.V619A | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100241220; called by muse, mutect2, varscan2
- C14orf93 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs758103437, COSV54441813; called by muse, mutect2, varscan2
- C17orf78 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 67/313 reads (21%) | catalogued as rs369234656; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 36/142 reads (25%) | catalogued as rs1558068270; called by mutect2, varscan2
- C2CD2L | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.036); catalogued as COSV100371183; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 48/242 reads (20%) | catalogued as rs372345940; called by mutect2, varscan2
- CABP4 | c.141del p.L48Sfs*84 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs773731650; called by mutect2, pindel, varscan2
- CACNA1F | c.1744G>A p.G582S | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1198536265, COSV100544728; called by muse, mutect2
- CACNA1I | c.4357C>T p.R1453W | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1410523453, COSV100360094; called by muse, varscan2
- CACNB2 | c.1018G>A p.A340T (on ENST00000324631 / NM_201596.3; = p.A285T on NM_000724.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.479); catalogued as rs140614930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADPS2 | c.354G>C p.Q118H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100462559; called by muse, mutect2, varscan2
- CARD6 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs183932779; called by muse, mutect2, varscan2
- CARMIL3 | c.2858C>T p.T953I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100549554; called by muse, mutect2, varscan2
- CASP14 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs751321912, COSV99693009; called by muse, mutect2, varscan2
- CCDC141 | c.3268A>T p.I1090F | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV55384336; called by muse, mutect2, varscan2
- CCDC65 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99872764; called by muse, mutect2, varscan2
- CCDC73 | c.208-2A>G p.X70_splice | Splice Site (SNP) | VAF 26/150 reads (17%) | catalogued as COSV100067304; called by muse, mutect2, varscan2
- CCNT1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs575488596, COSV56066300; called by muse, mutect2, varscan2
- CD109 | c.3192T>C p.P1064= | Splice Region (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99753472; called by muse, mutect2, varscan2
- CD46 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747504551, COSV100522868; called by muse, mutect2, varscan2
- CD70 | c.233del p.G78Afs*33 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as COSV99835502; called by mutect2, pindel, varscan2
- CD82 | c.623A>G p.D208G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.345); catalogued as COSV99907534; called by muse, varscan2
- CDC27 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV50707129; called by muse, mutect2, varscan2
- CDC40 | c.1085A>C p.E362A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100309273; called by muse, mutect2, varscan2
- CDH11 | c.1159A>G p.S387G | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV99218206; called by muse, varscan2
- CDH4 | c.1566dup p.G523Rfs*13 | Frame Shift Ins (INS) | VAF 12/71 reads (17%) | catalogued as rs764543058; called by mutect2, pindel, varscan2
- CDH7 | c.982-2A>C p.X328_splice | Splice Site (SNP) | VAF 18/104 reads (17%) | catalogued as COSV100542244; called by muse, mutect2, varscan2
- CDHR2 | c.2363del p.G788Vfs*4 | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | catalogued as rs868286996; called by mutect2, pindel, varscan2
- CDK12 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1488101050, COSV71000036; called by muse, mutect2, varscan2
- CEBPA | c.955A>G p.S319G | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as COSV100204536; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 45/218 reads (21%) | catalogued as rs375852685; called by mutect2, varscan2
- CEP162 | c.2761dup p.I921Nfs*9 | Frame Shift Ins (INS) | VAF 14/103 reads (14%) | catalogued as rs1562026955; called by mutect2, varscan2
- CEP290 | c.6147A>G p.I2049M | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV100468599; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 36/146 reads (25%) | catalogued as rs768479535; called by mutect2, varscan2
- CES5A | c.352T>C p.S118P | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99307484; called by muse, mutect2, varscan2
- CFAP299 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs765782959, COSV63872319; called by muse, varscan2
- CHD9 | c.6019G>A p.A2007T | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99529109; called by muse, mutect2, varscan2
- CHRDL2 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV55223010; called by muse, mutect2, varscan2
- CHST10 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as rs148953500; called by muse, mutect2, varscan2
- CIC | c.3596G>A p.R1199Q | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); catalogued as rs772474536, COSV99359486; called by muse, varscan2
- CILP | c.2645G>T p.R882M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV56024902; called by muse, mutect2, varscan2
- CLCN4 | c.144+2T>C p.X48_splice | Splice Site (SNP) | VAF 7/128 reads (5%) | catalogued as COSV101073788; called by muse, mutect2
- CLCN7 | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.879); catalogued as COSV51970535, COSV99247227; called by muse, mutect2, varscan2
- CLDN8 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 117/507 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs778089405, COSV54525752; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 42/146 reads (29%) | catalogued as rs758841384; called by mutect2, pindel, varscan2
- CMYA5 | c.959A>G p.H320R | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs371803314, COSV71409648; called by muse, mutect2, varscan2
- CNTN3 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99724234; called by muse, mutect2, varscan2
- COL14A1 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs200320717; called by mutect2, varscan2
- COL15A1 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1057094442, COSV100897628; called by muse, mutect2, varscan2
- COL4A5 | c.3632G>T p.G1211V | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960390, COSV100087562; called by muse, mutect2, varscan2
- COQ6 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99473882; called by muse, mutect2, varscan2
- CORO2B | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs370083446, COSV55951128; called by mutect2, varscan2
- CPEB4 | c.1962+2T>C p.X654_splice | Splice Site (SNP) | VAF 16/73 reads (22%) | catalogued as COSV54177007; called by muse, mutect2, varscan2
- CPSF1 | c.1264_1266del p.K422del | In Frame Del (DEL) | VAF 34/186 reads (18%) | catalogued as rs782791660; called by pindel, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 73/377 reads (19%) | catalogued as rs747832403; called by mutect2, varscan2
- CRMP1 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV100271795; called by muse, mutect2
- CRYGS | c.402G>T p.E134D | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV100329981; called by muse, mutect2, varscan2
- CSMD1 | c.8407G>T p.V2803L (on ENST00000520002; = p.V2802L on NM_033225.6) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.629); catalogued as COSV59349219; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 39/212 reads (18%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTAGE1 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 128/608 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV66945319; called by muse, mutect2, varscan2
- CTC1 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100236391; called by muse, mutect2, varscan2
- CYLC1 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 50/415 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV61416019; called by muse, mutect2, varscan2
- CYP2A6 | c.1082G>T p.R361I | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199522873, COSV99991825, COSV99991837; called by muse, mutect2, varscan2
- CYP2S1 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs755173146, COSV100027450; called by muse, mutect2, varscan2
- CYP2W1 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100417176; called by muse, mutect2
- CYP4F12 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.594); catalogued as rs189002430; called by muse, mutect2, varscan2
- DACT1 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100241820; called by muse, mutect2, varscan2
- DCAF7 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60407070; called by muse, mutect2, varscan2
- DCLK2 | c.2239del p.H747Tfs*153 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as rs751255369; called by mutect2, pindel, varscan2
- DCLRE1A | c.2599A>G p.T867A | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV100800337; called by muse, mutect2, varscan2
- DCP2 | c.1234A>G p.N412D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV101203877; called by muse, mutect2, varscan2
- DDX11 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 60/644 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV52512526; called by muse, mutect2
- DDX54 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013839; called by muse, mutect2, varscan2
- DDX58 | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.203); catalogued as rs751722546, COSV59378519; called by muse, mutect2, varscan2
- DDX60L | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV99487546; called by muse, mutect2, varscan2
- DEGS1 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100083342; called by muse, mutect2, varscan2
- DENND1A | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs766053621, COSV101010556; called by muse, mutect2, varscan2
- DENND2B | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs757430136, COSV58205313; called by muse, mutect2, varscan2
- DGKH | c.2539G>A p.V847M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229586089, COSV99818731; called by muse, mutect2, varscan2
- DHX37 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1440910020, COSV100439211; called by muse, mutect2, varscan2
- DHX38 | c.217_219del p.K73del | In Frame Del (DEL) | VAF 20/88 reads (23%) | catalogued as rs1485550444; called by pindel, varscan2
- DIS3L | c.2861G>A p.R954K (on ENST00000319212 / NM_001143688.3; = p.R871K on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV56020880, COSV99972361; called by muse, mutect2, varscan2
- DLEC1 | c.1554G>A p.W518* | Nonsense Mutation (SNP) | VAF 28/117 reads (24%) | catalogued as COSV100342148; called by muse, mutect2, varscan2
- DLG3 | c.1441C>T p.R481* (on ENST00000374360 / NM_021120.4; = p.R144* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as rs1028686595, COSV99529475; called by muse, mutect2, varscan2
- DLGAP2 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs771268282, COSV101421782; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs762874947; called by mutect2, varscan2
- DMD | c.2172G>T p.L724F | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55906895; called by muse, mutect2, varscan2
- DMXL1 | c.7121C>T p.S2374L | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100223850; called by muse, mutect2, varscan2
- DNAH7 | c.3512G>A p.R1171Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746376803, COSV56753545, COSV56758533; called by muse, mutect2, varscan2
- DOCK6 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.54); catalogued as COSV52949825; called by muse, mutect2, varscan2
- DOK1 | c.1025A>G p.E342G | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV51216705; called by muse, mutect2
- DST | c.409T>G p.F137V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100418627, COSV56852760; called by muse, varscan2
- DSTN | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99855142; called by muse, mutect2, varscan2
- DTD2 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100180084; called by muse, mutect2, varscan2
- ECPAS | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); catalogued as rs760760389, COSV52211443; called by muse, mutect2, varscan2
- EDC4 | c.2032C>A p.R678S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV59304184; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1379C>T p.P460L (on ENST00000361735 / NM_015935.5; = p.P374L on NM_014955.3) | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs144305462; called by muse, mutect2, varscan2
- EFCAB13 | c.1024del p.S342Afs*25 | Frame Shift Del (DEL) | VAF 47/205 reads (23%) | catalogued as rs759569556; called by mutect2, pindel, varscan2
- EFR3A | c.1546del p.C516Afs*8 | Frame Shift Del (DEL) | VAF 47/307 reads (15%) | catalogued as COSV54462614; called by mutect2, pindel, varscan2
- EHD2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54407896, COSV99621506; called by muse, mutect2, varscan2
- EHMT2 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV64994297; called by muse, mutect2, varscan2
- EIF2B4 | c.509G>A p.R170Q (on ENST00000347454 / NM_001034116.2; = p.R169Q on NM_015636.3) | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.195); catalogued as rs1439504604, COSV99277553; called by muse, mutect2
- ELL | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99442908, COSV99443118; called by muse, mutect2, varscan2
- EML5 | c.5297C>T p.S1766F (on ENST00000380664; = p.S1774F on NM_183387.3) | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100715558, COSV61341356; called by muse, varscan2
- EML5 | c.3653A>G p.K1218R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs758429917, COSV100715561; called by muse, mutect2, varscan2
- ENDOU | c.1165T>C p.W389R (on ENST00000422538 / NM_001172439.2; = p.W348R on NM_006025.4) | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99139286; called by muse, mutect2, varscan2
- ENTPD4 | c.1312A>G p.T438A | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs780208873, COSV62269210; called by muse, mutect2, varscan2
- EPB41L2 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100440630; called by muse, mutect2, varscan2
- EPHB1 | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101213134; called by muse, mutect2, varscan2
- EPS8L2 | c.1072T>C p.C358R | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs369273038; called by muse, mutect2, varscan2
- ERC2 | c.2770C>T p.H924Y | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV99884128; called by muse, mutect2, varscan2
- ERN2 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99890578, COSV99891413; called by muse, mutect2, varscan2
- ESRP1 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.316); catalogued as COSV64410882; called by muse, mutect2, varscan2
- ETV3L | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs765556753, COSV71901012, COSV71901134; called by muse, mutect2, varscan2
- EVC2 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.207); catalogued as rs544632500, COSV60394709; called by muse, mutect2, varscan2
- EVPL | c.4645G>A p.A1549T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100044431; called by muse, mutect2
- EVPL | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV100044432; called by muse, mutect2, varscan2
- EXOC3L1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.068); catalogued as COSV52048739; called by muse, mutect2, varscan2
- EXOSC3 | c.626+2T>C p.X209_splice | Splice Site (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99956017; called by muse, mutect2, varscan2
- EZHIP | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100539660; called by muse, mutect2, varscan2
- FAM135B | c.3922G>A p.V1308I | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.928); catalogued as rs759696683, COSV52702423; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 30/105 reads (29%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM162A | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99216348; called by muse, mutect2, varscan2
- FAM186B | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as rs138755693; called by muse, mutect2, varscan2
- FAM24A | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV100925080; called by muse, mutect2, varscan2
- FAM83B | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100174423; called by muse, mutect2, varscan2
- FANCM | c.4418A>T p.N1473I | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99950990; called by muse, varscan2
- FBH1 | c.401C>A p.A134D (on ENST00000362091 / NM_178150.3; = p.A185D on NM_032807.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.069); catalogued as rs1317810663, COSV100758726; called by muse, mutect2, varscan2
- FBLN1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.265); catalogued as COSV53055125; called by muse, mutect2, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXO24 | c.1033del p.L345Wfs*45 (on ENST00000241071 / NM_033506.3; = p.L383Wfs*45 on NM_012172.5) | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs1236194155; called by mutect2, pindel, varscan2
- FBXW5 | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV99812460; called by muse, mutect2, varscan2
- FEZF2 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99334682; called by muse, mutect2, varscan2
- FGD2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs367888863; called by muse, mutect2, varscan2
- FGF2 | c.17del p.G6Vfs*4 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs776164719; called by mutect2, pindel, varscan2
- FGF20 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1253072793, COSV51661116; called by muse, mutect2, varscan2
- FHDC1 | c.1315del p.T439Pfs*2 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | catalogued as rs1303890230; called by mutect2, pindel, varscan2
- FIGN | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as rs750122544, COSV100292303; called by muse, mutect2, varscan2
- FKBP10 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs782261801, COSV58636752; called by muse, mutect2, varscan2
- FLNC | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs763968152, COSV57952486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.6526C>T p.R2176C | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs376885778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.2819C>T p.A940V | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs746668767, COSV60448783; called by muse, varscan2
- FN1 | c.4071T>C p.G1357= | Splice Region (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100117041; called by muse, mutect2, varscan2
- FNDC3A | c.3239A>G p.Y1080C (on ENST00000492622 / NM_001079673.2; = p.Y1024C on NM_014923.5) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101256705; called by muse, mutect2, varscan2
- FOXD4L5 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 88/878 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs1158415338, COSV101073055; called by muse, mutect2
- FOXG1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV57395638; called by muse, mutect2, varscan2
- FOXH1 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100023751; called by muse, mutect2, varscan2
- FOXO4 | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.091); catalogued as COSV100446879; called by muse, mutect2, varscan2
- FRAS1 | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.397); catalogued as COSV53655798; called by muse, mutect2, varscan2
- FRMPD4 | c.1856A>C p.E619A | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV101042771; called by muse, mutect2, varscan2
- FRRS1 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV99789858; called by muse, mutect2, varscan2
- FRY | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.78); catalogued as COSV100969182; called by muse, mutect2, varscan2
- FSD2 | c.1646del p.G549Afs*4 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs1246402267; called by mutect2, pindel, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- FYN | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991286, COSV99991657; called by muse, mutect2, varscan2
- GABRA5 | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV59476077; called by muse, mutect2, varscan2
- GABRB2 | c.661A>C p.K221Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV99195982; called by muse, mutect2, varscan2
- GABRE | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV64821776; called by muse, mutect2, varscan2
- GALNT15 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs756197962, COSV60217033; called by muse, mutect2, varscan2
- GALNTL6 | c.822A>C p.Q274H | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101560261; called by muse, mutect2, varscan2
- GANAB | c.1840G>A p.V614M | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as rs770506502, COSV60463395; called by muse, mutect2, varscan2
- GATAD2B | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64083908; called by muse, mutect2, varscan2
- GBF1 | c.146T>G p.V49G | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV100890462; called by muse, mutect2, varscan2
- GBP2 | c.668G>A p.C223Y | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs868380613, COSV100975380; called by muse, mutect2
- GCC2 | c.4988A>G p.E1663G | Missense Mutation (SNP) | VAF 97/530 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100474785; called by muse, mutect2, varscan2
- GCN1 | c.2969C>T p.T990M | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as rs762831193, COSV56114337; called by mutect2, varscan2
- GCSAML | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100825942; called by muse, mutect2, varscan2
- GDAP1L1 | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as rs749288709, COSV100697551; called by muse, mutect2, varscan2
- GGT5 | c.866del p.G289Vfs*11 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as COSV54073059; called by pindel, varscan2
- GLA | c.782del p.G261Vfs*8 | Frame Shift Del (DEL) | VAF 39/211 reads (18%) | catalogued as CM138881, CM972905; called by mutect2, pindel, varscan2
- GLG1 | c.979-2A>G p.X327_splice | Splice Site (SNP) | VAF 7/82 reads (9%) | catalogued as COSV99215709; called by muse, mutect2
- GLI2 | c.1732G>A p.V578I (on ENST00000361492 / NM_001374353.1; = p.V595I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as rs768557650, COSV58043749; called by muse, mutect2, varscan2
- GNA14 | c.34_36del p.K12del | In Frame Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs754882574; called by mutect2, pindel, varscan2
- GOLM1 | c.539dup p.N182Efs*2 | Frame Shift Ins (INS) | VAF 67/334 reads (20%) | catalogued as COSV57413786, COSV57413907; called by mutect2, pindel, varscan2
- GPR153 | c.1007del p.P336Rfs*20 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | catalogued as COSV64938744; called by mutect2, pindel, varscan2
- GPR78 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs61741001, COSV101223962; called by muse, mutect2, varscan2
- GPRASP2 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs759518487, COSV59991256, COSV59992544; called by muse, mutect2, varscan2
- GPS2 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs192050225, COSV59746973; called by muse, mutect2, varscan2
- GRIK3 | c.2316C>T p.G772= | Splice Region (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100901930; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as rs754199513; called by mutect2, varscan2
- GSK3A | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55899756; called by muse, mutect2, varscan2
- GTF2F1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs201557731, COSV101081058; called by muse, mutect2, varscan2
- GTPBP6 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as rs372906272, COSV100397724, COSV58204709; called by muse, mutect2, varscan2
- GUCY2F | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 43/214 reads (20%) | catalogued as COSV99484918; called by muse, mutect2, varscan2
- H2BC6 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV61591894; called by muse, mutect2, varscan2
- H2BW1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs782445882, COSV54220675; called by muse, mutect2, varscan2
- H3C6 | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs148426352; called by muse, varscan2
- HAP1 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs1555591934, COSV100169652; called by muse, mutect2, varscan2
- HDAC7 | c.2137G>A p.G713S (on ENST00000427332; = p.G752S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747647941, COSV99316089; called by muse, mutect2, varscan2
- HDLBP | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 36/246 reads (15%) | catalogued as COSV100190457, COSV100191452; called by muse, mutect2, varscan2
- HEATR1 | c.6218C>T p.T2073M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs200854169, COSV100120451; called by muse, mutect2, varscan2
- HEATR5B | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs372034610; called by muse, mutect2, varscan2
- HECTD4 | c.6209G>A p.R2070H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66387540; called by muse, mutect2, varscan2
- HEMGN | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs142085732; called by muse, mutect2, varscan2
- HGSNAT | c.133del p.R45Dfs*5 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs1220771600; called by mutect2, varscan2
- HIC2 | c.686del p.G229Afs*45 | Frame Shift Del (DEL) | VAF 36/157 reads (23%) | catalogued as rs1218980629; called by mutect2, pindel, varscan2
- HIF1AN | c.484T>G p.F162V | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100142668; called by muse, mutect2, varscan2
- HNF1A | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs373857078; called by muse, mutect2, varscan2
- HS6ST1 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99389538; called by muse, mutect2, varscan2
- HSPA1A | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs756347651, COSV100989378; called by muse, varscan2
- HSPB9 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs1555668015, COSV56791863; called by muse, mutect2, varscan2
- HUWE1 | c.12437T>C p.M4146T | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99472031; called by muse, mutect2, varscan2
- IFT80 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs535870220, COSV100424679, COSV58447488; called by muse, mutect2, varscan2
- IGSF10 | c.3148del p.S1050Afs*12 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs34882912; called by mutect2, pindel, varscan2
- IL25 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 95/436 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs375340039; called by muse, mutect2, varscan2
- IQSEC1 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.724); catalogued as rs535113723, COSV56223793; called by muse, mutect2, varscan2
- IRF2BPL | c.1298G>T p.S433I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV99468049; called by muse, mutect2, varscan2
- IRF6 | c.171del p.F57Lfs*6 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as CM097106; called by pindel, varscan2
- IRGQ | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60670747; called by muse, mutect2, varscan2
- ITGB1 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56487708; called by muse, mutect2, varscan2
- ITIH1 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs767332893, COSV99835195, COSV99835271; called by muse, mutect2, varscan2
- ITIH2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs377111707; called by muse, mutect2, varscan2
- ITK | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101439702; called by muse, mutect2, varscan2
- ITPRIPL2 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs1466100646, COSV67348182; called by muse, mutect2, varscan2
- JADE1 | c.1106G>A p.S369N | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99885717; called by muse, mutect2, varscan2
- KAT8 | c.1198C>A p.L400M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99571409; called by muse, mutect2, varscan2
- KCNA6 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99768467; called by muse, mutect2, varscan2
- KCNAB1 | c.276-2A>G p.X92_splice (on ENST00000490337 / NM_172160.3; = p.X81_splice on NM_003471.3) | Splice Site (SNP) | VAF 32/154 reads (21%) | catalogued as COSV100204252; called by muse, mutect2, varscan2
- KCNK13 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | catalogued as rs565658757, COSV56410665; called by muse, mutect2, varscan2
- KCNK15 | c.695T>C p.L232P | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100865116; called by muse, mutect2, varscan2
- KCTD8 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63586851; called by muse, mutect2
- KDM5C | c.3841C>A p.L1281I | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100949102; called by muse, mutect2, varscan2
- KDM6B | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs768893856, COSV99641286; called by muse, mutect2, varscan2
- KHDC3L | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.78); catalogued as rs1159857446, COSV64863683; called by muse, mutect2, varscan2
- KIF12 | c.869G>A p.S290N (on ENST00000640217; = p.S152N on NM_138424.1) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.113); catalogued as COSV65118582; called by muse, mutect2, varscan2
- KIF18B | c.312A>G p.S104= | Splice Region (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100192097; called by muse, mutect2, varscan2
- KIF23 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.268); catalogued as rs1264628335, COSV99532294; called by muse, mutect2
- KIF26A | c.3770C>T p.A1257V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV100181088; called by muse, mutect2, varscan2
- KIF2B | c.626del p.P209Rfs*10 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as COSV52136659; called by mutect2, pindel, varscan2
- KIF4B | c.3475C>T p.P1159S | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772431228, COSV70531901; called by muse, mutect2, varscan2
- KIF7 | c.2225G>A p.S742N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs1440715352, COSV67999813; called by muse, mutect2, varscan2
- KIF9 | c.1796A>T p.N599I (on ENST00000265529 / NM_001377474.1; = p.N534I on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/247 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99646657; called by muse, mutect2
- KLHDC7B | c.326C>T p.A109V (on ENST00000395676; = p.A750V on NM_138433.5) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV67465351; called by muse, mutect2, varscan2
- KLHL1 | c.2135C>T p.T712I | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1251808901, COSV64775972; called by muse, mutect2, varscan2
- KLHL23 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.1); catalogued as COSV99775759; called by muse, mutect2, varscan2
- KLHL4 | c.1160G>T p.S387I | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1282305368, COSV100909509; called by muse, mutect2, varscan2
- KLHL8 | c.1014C>A p.C338* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | catalogued as COSV99911351; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2E | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99996259; called by muse, mutect2, varscan2
- KREMEN1 | c.850G>A p.G284R (on ENST00000407188; = p.G286R on NM_032045.5) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs751542642, COSV59911527; called by muse, mutect2, varscan2
- L1CAM | c.3433C>T p.R1145C | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200798819, COSV100649090; called by muse, mutect2, varscan2
- LAMA5 | c.6575T>C p.L2192P | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99439718; called by muse, mutect2, varscan2
- LAMB1 | c.5125del p.T1709Lfs*22 | Frame Shift Del (DEL) | VAF 29/200 reads (15%) | catalogued as rs1441388757; called by mutect2, pindel, varscan2
- LAPTM4A | c.525del p.F175Lfs*5 | Frame Shift Del (DEL) | VAF 70/338 reads (21%) | catalogued as rs1476796878; called by mutect2, pindel, varscan2
- LCP1 | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100549852; called by muse, mutect2, varscan2
- LEPROTL1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs974543255, COSV58304364, COSV58304994; called by muse, mutect2, varscan2
- LHPP | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs370925915, COSV100919315; called by muse, mutect2, varscan2
- LINGO2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs1016504624, COSV58064143; called by muse, mutect2, varscan2
- LMNB2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs367908162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMOD2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV71755718; called by muse, varscan2
- LNX1 | c.388G>A p.G130S (on ENST00000263925 / NM_001126328.3; = p.G34S on NM_032622.2) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99819922; called by muse, mutect2, varscan2
- LPO | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as rs772131545, COSV51863337; called by muse, mutect2, varscan2
- LRFN5 | c.866T>G p.I289S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99983628; called by muse, mutect2, varscan2
- LRP2 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749942746, COSV55543681; called by muse, mutect2, varscan2
- LRR1 | c.737G>A p.C246Y | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100023100; called by muse, mutect2, varscan2
- LRRC36 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV99338674; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs1557715031, COSV58440688; called by mutect2, pindel, varscan2
- LRRC66 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV58636381, COSV58636463; called by muse, mutect2, varscan2
- LRRK2 | c.3068T>C p.L1023P | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110050, COSV54169871; called by muse, mutect2, varscan2
- LRRN3 | c.1268T>A p.I423K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV100070198; called by muse, mutect2, varscan2
- LSR | c.857C>T p.P286L (on ENST00000361790; = p.P267L on NM_015925.6) | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1334673244, COSV100670452; called by muse, mutect2, varscan2
- LTBP2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765793427, COSV100000207; called by muse, mutect2, varscan2
- LTF | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs765686239, COSV51609053; called by muse, mutect2, varscan2
- LUZP1 | c.422T>G p.L141R | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100034846; called by muse, mutect2, varscan2
- LZTS2 | c.303del p.S102Afs*41 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs1460451498; called by mutect2, pindel, varscan2
- M6PR | c.159A>C p.K53N | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV99134173; called by muse, mutect2
- MAB21L3 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.373); catalogued as COSV101046373; called by muse, mutect2, varscan2
- MAEL | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV63305855; called by muse, mutect2, varscan2
- MAFK | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431215647, COSV99868167; called by muse, mutect2, varscan2
- MAP2K6 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | catalogued as rs753824437, COSV100765074; called by muse, mutect2, varscan2
- MAP3K4 | c.4514C>T p.T1505I | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815321; called by muse, mutect2, varscan2
- MAP7D1 | c.1465A>G p.T489A | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs767558715, COSV60219146; called by muse, mutect2, varscan2
- MAPK8IP2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV50508869; called by muse, mutect2
- MASP1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1170038123, COSV99397137; called by muse, varscan2
- MAST4 | c.2071C>T p.H691Y (on ENST00000403625 / NM_001164664.2; = p.H502Y on NM_015183.3) | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99844027; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | catalogued as rs1203662025; called by mutect2, varscan2
- MAU2 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV99448649; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs746267361; called by mutect2, varscan2
- MDN1 | c.11461A>G p.M3821V | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs17214794; called by muse, mutect2, varscan2
- MEAK7 | c.688C>A p.L230M | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100640394; called by muse, mutect2, varscan2
- MEPE | c.831A>C p.E277D | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV63073930; called by muse, mutect2, varscan2
- MICALL1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs1361536769, COSV99317232; called by muse, mutect2, varscan2
- MIEF2 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs757255286, COSV100544081; called by muse, mutect2, varscan2
- MLH1 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM123004, COSV51615129, COSV99212419; called by muse, mutect2
- MLNR | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as COSV99519825; called by muse, mutect2, varscan2
- MMS19 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs927043964, COSV100512831; called by muse, mutect2, varscan2
- MOGAT2 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs776690691, COSV52220556; called by muse, mutect2, varscan2
- MT1G | c.185C>T p.A62V (on ENST00000379811 / NM_001301267.2; = p.A61V on NM_005950.3) | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.399); catalogued as COSV60091778; called by muse, mutect2, varscan2
- MTHFD1L | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs139147258; called by muse, mutect2, varscan2
- MUC16 | c.3560C>G p.T1187S | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as COSV101199710; called by muse, mutect2, varscan2
- MUC21 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.146); catalogued as COSV100888860; called by muse, mutect2, varscan2
- MUC21 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 92/382 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761798063, COSV66220632; called by muse, mutect2, varscan2
- MUTYH | c.158-2A>C p.X53_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as rs751914222, COSV58345134; ClinVar: likely benign; called by muse, mutect2, varscan2
- MVB12A | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1473494833, COSV100396492; called by muse, mutect2, varscan2
- MYH7 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100806052; called by muse, mutect2
- MYH7B | c.4510C>T p.R1504W | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771512439, COSV52685284; called by muse, mutect2, varscan2
- MYH8 | c.2446T>G p.C816G | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV101238393; called by muse, mutect2, varscan2
- MYO18A | c.5707G>A p.E1903K | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs770633780, COSV62874866; called by muse, mutect2, varscan2
- MYO18A | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV62874873; called by muse, mutect2, varscan2
- MYO18A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV62874880; called by muse, mutect2, varscan2
- MYO9A | c.2522+1G>A p.X841_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100613341; called by muse, mutect2, varscan2
- MYOCD | c.374dup p.N125Kfs*16 | Frame Shift Ins (INS) | VAF 21/122 reads (17%) | catalogued as rs1567587048; called by mutect2, varscan2
- MZT2B | c.440del p.G147Afs*? | Frame Shift Del (DEL) | VAF 35/198 reads (18%) | catalogued as rs772879277; called by mutect2, pindel, varscan2
- NAPB | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100582498; called by muse, mutect2, varscan2
- NAPSA | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs186910155, COSV99515824; called by muse, mutect2, varscan2
- NAT8L | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as COSV59051023; called by muse, mutect2, varscan2
- NAV2 | c.7247G>A p.R2416Q (on ENST00000396087 / NM_001244963.2; = p.R2357Q on NM_145117.5) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs758719814, COSV100216783; called by muse, mutect2, varscan2
- NCKAP1 | c.2321A>G p.Q774R | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as COSV100720208; called by muse, mutect2, varscan2
- NCKIPSD | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1221316342, COSV53660460; called by muse, mutect2, varscan2
- NCOA7 | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as rs1300236722, COSV99997042; called by muse, mutect2, varscan2
- NDUFB11 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV99333306; called by muse, mutect2
- NEK9 | c.2906T>G p.L969R | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99464015; called by muse, mutect2, varscan2
- NEMF | c.800T>C p.I267T | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100027606; called by muse, mutect2, varscan2
- NEUROG1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 67/291 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100130781, COSV59082293; called by muse, mutect2, varscan2
- NFATC2 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs867932067, COSV65356193; called by muse, mutect2, varscan2
- NHS | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs771048907, COSV66273272; called by muse, mutect2, varscan2
- NID1 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs144659138, COSV51614371; called by muse, mutect2, varscan2
- NINL | c.2311C>T p.R771C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs776042146, COSV54002559; called by muse, mutect2, varscan2
- NIPAL4 | c.1138T>C p.Y380H | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1210461038, COSV57440675; called by muse, mutect2, varscan2
- NIPSNAP2 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 88/414 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV100436695; called by muse, mutect2, varscan2
- NKIRAS2 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); catalogued as rs781878749, COSV100288809; called by muse, mutect2, varscan2
- NOL6 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs369599517; called by muse, mutect2, varscan2
- NOL7 | c.714dup p.Q239Tfs*7 | Frame Shift Ins (INS) | VAF 45/238 reads (19%) | catalogued as rs544905440; called by mutect2, varscan2
- NOS3 | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52493505; called by muse, mutect2, varscan2
- NPAS1 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV101463935; called by muse, mutect2, varscan2
- NSUN5 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1554541336, COSV99392351; called by muse, mutect2, varscan2
- NT5E | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs775412849, COSV57630435; called by muse, mutect2, varscan2
- NTHL1 | c.374del p.P125Qfs*12 (on ENST00000219066; = p.P117Qfs*12 on NM_002528.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | catalogued as rs763525759; called by mutect2, pindel, varscan2
- NUP107 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99971715; called by muse, mutect2, varscan2
- NUP205 | c.1199T>A p.L400H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99606939; called by muse, mutect2, varscan2
- OBSCN | c.15022C>T p.R5008C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs750047152, COSV99477052; called by muse, mutect2, varscan2
- OR1G1 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1419481787, COSV100187539; called by muse, mutect2, varscan2
- OR51M1 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100150228; called by muse, mutect2, varscan2
- OR5W2 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV100747610; called by muse, mutect2, varscan2
- OR6N1 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs751230252, COSV100625157; called by muse, mutect2, varscan2
- OR8H1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV57296109; called by muse, mutect2
- OSBPL10 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.691); catalogued as rs367556908, COSV67338559; called by muse, mutect2, varscan2
- OSM | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | catalogued as rs150499755, COSV53160967; called by mutect2, pindel, varscan2
- OXNAD1 | c.334T>C p.S112P | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99551195; called by muse, mutect2, varscan2
- PACSIN2 | c.621G>C p.K207N | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV99606176; called by muse, mutect2, varscan2
- PAK6 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs751201488, COSV53047781; called by muse, mutect2, varscan2
- PAPPA2 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.099); catalogued as COSV62788354; called by muse, mutect2, varscan2
- PARD6G | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs776972451, COSV100783395; called by muse, mutect2, varscan2
- PARP4 | c.2905T>C p.S969P | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.369); catalogued as COSV101131585; called by muse, mutect2, varscan2
- PASD1 | c.1440G>A p.Q480= | Splice Region (SNP) | VAF 26/120 reads (22%) | catalogued as COSV100949318; called by muse, mutect2, varscan2
- PBXIP1 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs762352663, COSV100870068; called by muse, mutect2, varscan2
- PCDHA12 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 119/466 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV56510774; called by muse, mutect2, varscan2
- PCDHA4 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs782455641, COSV63543263; called by muse, mutect2, varscan2
- PCDHB3 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782801316, COSV50589763; called by muse, mutect2, varscan2
- PCDHB7 | c.1424C>A p.A475D | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99176898; called by muse, mutect2, varscan2
- PCDHB8 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.05); catalogued as rs782003552, COSV50754292; called by muse, mutect2, varscan2
- PCDHGA1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as rs1237215414, COSV65295658; called by muse, mutect2, varscan2
- PCDHGB4 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV53968908, COSV99540531; called by muse, mutect2, varscan2
- PCDHGB7 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs1331897624, COSV53893265; called by muse, mutect2, varscan2
- PCED1A | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs199975004; called by muse, mutect2, varscan2
- PCID2 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371915766, COSV99872451; called by muse, mutect2, varscan2
- PCNX3 | c.3728G>A p.R1243H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as rs756949255, COSV100856341; called by muse, mutect2, varscan2
- PDE11A | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1045114170, COSV99612052; called by muse, mutect2, varscan2
- PDE6C | c.1381A>T p.K461* | Nonsense Mutation (SNP) | VAF 36/176 reads (20%) | catalogued as COSV101008717; called by muse, mutect2, varscan2
- PDXDC1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs368974427, COSV57903259; called by muse, mutect2, varscan2
- PER3 | c.1250T>C p.V417A | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV100728322; called by muse, mutect2
- PFKL | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60363428; called by muse, mutect2, varscan2
- PGBD5 | c.287C>T p.T96M (on ENST00000525115; = p.T165M on NM_001258311.2) | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs534656022, COSV58411437; called by muse, mutect2, varscan2
- PHF3 | c.2910dup p.R971Sfs*6 | Frame Shift Ins (INS) | VAF 39/271 reads (14%) | catalogued as rs755026826; called by mutect2, varscan2
- PIANP | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs181795908, COSV57708603; called by muse, mutect2
- PIAS4 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs761178452, COSV53681482; called by muse, mutect2, varscan2
- PIGM | c.1152C>A p.N384K | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100928037; called by muse, mutect2
- PLA2G6 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs772176591, COSV100140212, COSV59270870; called by muse, mutect2, varscan2
- PLCG2 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs926237449, COSV100842120, COSV63875469; called by muse, mutect2, varscan2
- PLEKHA2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 91/477 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751041165, COSV66242477, COSV66242650; called by muse, mutect2, varscan2
- PLEKHN1 | c.1003C>T p.R335C (on ENST00000379409; = p.R283C on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs369409460, COSV100379091; called by muse, mutect2, varscan2
- PLK1 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267164; called by muse, mutect2, varscan2
- PLOD2 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs368177696; called by muse, varscan2
- PLXNA1 | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99302926; called by muse, mutect2, varscan2
- PNLIP | c.1236G>T p.L412F | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100981785; called by muse, mutect2, varscan2
- PNMA8A | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs116822170, COSV58138102, COSV58139624; called by muse, mutect2, varscan2
- POGLUT1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99809567; called by muse, mutect2
- POLN | c.1013G>A p.W338* | Nonsense Mutation (SNP) | VAF 60/297 reads (20%) | catalogued as rs754691451, COSV101242505; called by muse, mutect2, varscan2
- POLR3D | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs967660557, COSV100120080; called by muse, mutect2, varscan2
- POR | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs1348920221, COSV100115565; called by muse, varscan2
- POU2AF1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as rs1183286104, COSV101260605; called by muse, mutect2, varscan2
- POU3F2 | c.943C>A p.Q315K | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100099141; called by muse, mutect2, varscan2
- PPFIA1 | c.865A>T p.T289S | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs1282738471, COSV99557351; called by muse, mutect2, varscan2
- PPM1D | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100010837; called by muse, mutect2, varscan2
- PPM1L | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 9/114 reads (8%) | catalogued as COSV55560921, COSV99861825; called by muse, mutect2
- PPP1R14A | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100007294; called by muse, varscan2
- PPP1R3C | c.474_477del p.C158Wfs*11 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs748227180; called by pindel, varscan2
- PPP3CA | c.230del p.N77Ifs*22 | Frame Shift Del (DEL) | VAF 23/148 reads (16%) | catalogued as rs1250808026; called by mutect2, pindel, varscan2
- PRAM1 | c.788A>G p.K263R | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV55313352; called by muse, mutect2
- PRDM10 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1484112394, COSV58799636; called by muse, mutect2, varscan2
- PRDM13 | c.2062G>A p.V688I | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100980480; called by muse, mutect2, varscan2
- PRICKLE3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376861498, COSV100889883; called by muse, mutect2, varscan2
- PRKDC | c.10844C>T p.A3615V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV58066585; called by muse, varscan2
- PSRC1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs754495062, COSV64020992; called by muse, mutect2, varscan2
- PTBP3 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV99270238; called by muse, mutect2, varscan2
- PTK2B | c.2413C>T p.R805W | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs771523736, COSV57749808; called by muse, mutect2, varscan2
- PTPN13 | c.855del p.K285Nfs*45 | Frame Shift Del (DEL) | VAF 29/132 reads (22%) | catalogued as rs754278242; called by mutect2, varscan2
- PTPN13 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs529404601, COSV57402113; called by muse, mutect2, varscan2
- PTPRD | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs376714429; called by muse, mutect2, varscan2
- PVRIG | c.255del p.T86Pfs*238 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as rs1202619241; called by mutect2, pindel, varscan2
- PXDNL | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as rs200870550, CM1410450, COSV62496137; called by muse, mutect2, varscan2
- QARS1 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139730889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAB3D | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99708827; called by muse, mutect2, varscan2
- RAB4A | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1416962296, COSV100797048; called by muse, mutect2, varscan2
- RAPGEF2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52427297; called by muse, mutect2, varscan2
- RAPH1 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as rs576908552, COSV55590772; called by muse, mutect2, varscan2
- RASIP1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99710721; called by muse, mutect2, varscan2
- RBM25 | c.2408C>T p.S803L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV56201325; called by muse, mutect2
- RDH16 | c.815T>G p.L272R | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100660101; called by muse, mutect2, varscan2
- RETSAT | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99806013; called by muse, mutect2, varscan2
- REV1 | c.2861T>C p.V954A | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs1449636445, COSV99177198; called by muse, mutect2, varscan2
- RIF1 | c.4327C>T p.R1443* | Nonsense Mutation (SNP) | VAF 27/158 reads (17%) | catalogued as COSV54623911; called by muse, mutect2, varscan2
- RIMBP2 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs368697814; called by muse, mutect2, varscan2
- RIMS1 | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 24/124 reads (19%) | catalogued as COSV99326386; called by muse, mutect2, varscan2
- RIPK1 | c.1685C>T p.T562M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs367576973; called by muse, mutect2, varscan2
- RNF144A | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs758418992, COSV100305595; called by muse, mutect2, varscan2
- RNF213 | c.8546C>T p.A2849V | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771738412, COSV60392922; called by muse, mutect2, varscan2
- RNF213 | c.10667G>A p.R3556H | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs867299197, COSV60403898; called by muse, mutect2
- RNF43 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs747371137, COSV68458423; called by muse, mutect2, varscan2
- RNF6 | c.478A>G p.R160G | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV100644625; called by muse, mutect2, varscan2
- RNGTT | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs759501463, COSV99666350; called by muse, mutect2, varscan2
- RPL10L | c.329G>T p.R110M | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100022544; called by muse, mutect2, varscan2
- RPS5 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs761762077, COSV99544915; called by muse, mutect2, varscan2
- RPS6KA5 | c.1511_1513del p.G504del | In Frame Del (DEL) | VAF 20/91 reads (22%) | catalogued as rs767419873; called by pindel, varscan2
- RPUSD4 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53600464; called by muse, mutect2, varscan2
- RRBP1 | c.3395G>A p.R1132H (on ENST00000377813 / NM_001365613.2; = p.R699H on NM_004587.3) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773607835, COSV55709745; called by muse, mutect2, varscan2
- RREB1 | c.3524G>A p.S1175N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58567227; called by muse, mutect2, varscan2
- RTP5 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV58321823; called by muse, mutect2, varscan2
- RTTN | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99732177; called by muse, mutect2
- RXRA | c.331del p.L111Wfs*57 | Frame Shift Del (DEL) | VAF 16/180 reads (9%) | catalogued as COSV62684236; called by mutect2, pindel
- RYR1 | c.10577C>T p.A3526V | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs374061380, COSV100615550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.6710del p.G2237Efs*56 (on ENST00000389232; = p.G2237Efs*57 on NM_001036.6) | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | catalogued as rs751516213; called by mutect2, pindel, varscan2
- S100A13 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.141); catalogued as COSV52679818, COSV52679823; called by muse, mutect2, varscan2
- S1PR3 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as rs1294693271, COSV100822525; called by muse, mutect2, varscan2
- SACS | c.10453del p.I3485Lfs*10 | Frame Shift Del (DEL) | VAF 43/203 reads (21%) | catalogued as rs1052973590; called by mutect2, pindel, varscan2
- SAMD4A | c.1701T>A p.Y567* | Nonsense Mutation (SNP) | VAF 29/131 reads (22%) | catalogued as COSV99200642; called by muse, mutect2, varscan2
- SCAF1 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100862140; called by muse, mutect2, varscan2
- SCAF11 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991973393, COSV101014316; called by muse, mutect2, varscan2
- SCN5A | c.3520C>T p.R1174W (on ENST00000333535 / NM_198056.3; = p.R1173W on NM_000335.5) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs367906630; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC14L3 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761871849, COSV99307137; called by muse, mutect2, varscan2
- SEC16A | c.4513G>A p.D1505N | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs763211212, COSV51542637; called by muse, mutect2, varscan2
- SELENOI | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53144187; called by muse, mutect2, varscan2
- SELENOT | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs753546569, COSV101517711; called by muse, mutect2, varscan2
- SEMA5B | c.2797C>T p.R933C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52098645; called by muse, mutect2, varscan2
- SEPTIN14 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101193318; called by muse, mutect2, varscan2
- SFMBT1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs558266493, COSV99966045; called by muse, mutect2, varscan2
- SGIP1 | c.1699A>G p.T567A | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52780804; called by muse, mutect2, varscan2
- SH2D3A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201397651, COSV99837944; called by muse, mutect2, varscan2
- SHMT1 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV57400904; called by muse, mutect2, varscan2
- SHQ1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201983708, COSV57766890; called by muse, mutect2, varscan2
- SIDT1 | c.1219A>G p.T407A | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV99333806; called by muse, mutect2
- SIGLEC10 | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.555); catalogued as COSV59479061; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC13A5 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV99545875; called by muse, mutect2, varscan2
- SLC2A10 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100826362; called by muse, mutect2, varscan2
- SLC2A2 | c.421T>G p.L141V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100049291; called by muse, varscan2
- SLC30A9 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs144935504; called by muse, mutect2, varscan2
- SLC38A3 | c.1401del p.I469Sfs*13 | Frame Shift Del (DEL) | VAF 38/184 reads (21%) | catalogued as COSV68844080; called by mutect2, pindel, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 33/187 reads (18%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A9 | c.2737del p.L913Sfs*28 (on ENST00000507527 / NM_001258428.2; = p.L889Sfs*28 on NM_031467.3) | Frame Shift Del (DEL) | VAF 34/135 reads (25%) | catalogued as rs1157562442, COSV99140111; called by mutect2, pindel, varscan2
- SLC5A12 | c.724A>C p.T242P | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV54825709; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
- SLIT2 | c.3341C>A p.S1114Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV99883426; called by muse, varscan2
- SLTM | c.2389G>A p.V797I | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV100998652; called by muse, mutect2, varscan2
- SMARCA1 | c.2503A>T p.I835F | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV100946501; called by muse, mutect2, varscan2
- SMARCA2 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 15/139 reads (11%) | catalogued as COSV61813908; called by muse, mutect2, varscan2
- SMARCAD1 | c.2285T>A p.I762N | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV100758897; called by muse, mutect2, varscan2
- SMYD1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs186217134; called by muse, mutect2, varscan2
- SOD2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100496619; called by muse, mutect2, varscan2
- SOX6 | c.1269G>T p.Q423H (on ENST00000528429 / NM_001145819.2; = p.Q382H on NM_017508.3) | Missense Mutation (SNP) | VAF 88/391 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100322028; called by muse, mutect2, varscan2
- SPATC1 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs782013278, COSV101084934; called by muse, mutect2, varscan2
- SPDL1 | c.1175A>G p.Q392R | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99517512; called by muse, mutect2, varscan2
- SPI1 | c.373T>A p.S125T | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as COSV57046542, COSV99908873; called by muse, mutect2, varscan2
- SPPL2C | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs1460272713, COSV100234026, COSV61293180; called by muse, mutect2, varscan2
- SPTA1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs565907779, COSV63749834, COSV63750786; called by muse, mutect2, varscan2
- SPTBN1 | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.315); catalogued as rs1331965648, COSV61695290; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs748467821; called by mutect2, varscan2
- SSTR3 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60730567; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 38/195 reads (19%) | PolyPhen possibly damaging (0.692); catalogued as rs369940675; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAB1 | c.6776T>C p.L2259P | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1026187668, COSV100194871; called by muse, mutect2, varscan2
- STC2 | c.466A>T p.I156L | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99438336; called by muse, mutect2, varscan2
- SUPT5H | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs369717101, COSV100782093; called by muse, mutect2, varscan2
- SUPT6H | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.122); catalogued as COSV100112158; called by muse, mutect2, varscan2
- SYDE2 | c.2918T>C p.M973T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100415901; called by muse, mutect2, varscan2
- SYNC | c.1090A>G p.T364A | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.642); catalogued as COSV100995286; called by muse, mutect2, varscan2
- SYT3 | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.981); catalogued as COSV100144061; called by muse, mutect2, varscan2
- TAOK2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs1473676019, COSV54242081; called by muse, mutect2, varscan2
- TAS2R16 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.223); catalogued as COSV99972236; called by muse, mutect2, varscan2
- TBC1D17 | c.1216A>G p.T406A | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1218653442, COSV99680603; called by muse, mutect2, varscan2
- TBC1D4 | c.1080+2T>C p.X360_splice | Splice Site (SNP) | VAF 23/130 reads (18%) | catalogued as COSV100884593; called by muse, mutect2, varscan2
- TBKBP1 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100659103; called by muse, mutect2
- TCERG1 | c.841T>C p.S281P | Missense Mutation (SNP) | VAF 85/498 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.91); catalogued as COSV99694758; called by muse, mutect2, varscan2
- TCHH | c.3487C>T p.R1163C | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs1254693549, COSV64275591; called by muse, mutect2, varscan2
- TEDC1 | c.1265G>A p.G422D (on ENST00000392523 / NM_001367178.1; = p.G353D on NM_001134875.1) | Missense Mutation (SNP) | VAF 77/388 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.109); catalogued as COSV100322150; called by muse, mutect2, varscan2
- TENM1 | c.4921G>A p.A1641T | Missense Mutation (SNP) | VAF 148/648 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100949895; called by muse, mutect2, varscan2
- TENM3 | c.7769C>T p.T2590M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101305083; called by muse, mutect2, varscan2
- TEX15 | c.1388G>T p.S463I (on ENST00000256246; = p.S846I on NM_001350162.2) | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV99821266; called by muse, mutect2, varscan2
- THBD | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV101001879; called by muse, mutect2, varscan2
- THBS3 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100366805; called by muse, mutect2, varscan2
- THOC3 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs777994083, COSV99442093; called by muse, mutect2
- THSD7B | c.1524del p.G509Dfs*58 | Frame Shift Del (DEL) | VAF 34/187 reads (18%) | catalogued as rs1236522898, COSV55712401; called by mutect2, pindel, varscan2
- TKT | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99964998; called by muse, mutect2, varscan2
- TLR9 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs1214449391, COSV100645637; called by muse, mutect2, varscan2
- TLR9 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.062); catalogued as rs756045938, COSV100645638; called by muse, mutect2, varscan2
- TM7SF3 | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100544790; called by muse, mutect2, varscan2
- TMC3 | c.1846T>C p.S616P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845903; called by muse, mutect2, varscan2
- TMEM18 | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV99806149; called by muse, mutect2, varscan2
- TMPRSS12 | c.189T>G p.D63E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV101269104; called by muse, mutect2, varscan2
- TNC | c.3962C>A p.P1321H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV100405650; called by muse, mutect2, varscan2
- TNFRSF9 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as rs145966863; called by muse, mutect2, varscan2
- TNFSF12 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs1225175840, COSV99547222; called by muse, mutect2, varscan2
- TNNI1 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60190720; called by muse, mutect2, varscan2
- TOP3A | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0.021); catalogued as rs755827699, COSV100329057; called by muse, mutect2, varscan2
- TP53BP2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376720051; called by muse, mutect2, varscan2
- TPSD1 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs760273670; called by mutect2, varscan2
- TRIM41 | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100163219; called by muse, mutect2, varscan2
- TRMT6 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99177564; called by muse, mutect2, varscan2
- TRMT9B | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs766632690, COSV67948541; called by muse, mutect2, varscan2
- TRRAP | c.7024A>G p.M2342V (on ENST00000359863 / NM_001244580.1; = p.M2324V on NM_003496.3) | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100722418; called by muse, mutect2, varscan2
- TSC2 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54767256, COSV54782411; called by muse, mutect2, varscan2
- TSHR | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); catalogued as rs769777295, COSV53335974, COSV99991740; called by muse, mutect2, varscan2
- TSPAN6 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100885826; called by muse, mutect2, varscan2
- TSPYL2 | c.249del p.I84Sfs*63 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs1556807263; called by mutect2, pindel
- TTN | c.51129C>T p.C17043= (on ENST00000591111; = p.C9619= on NM_003319.4) | Splice Region (SNP) | VAF 8/47 reads (17%) | catalogued as COSV60435824; called by muse, mutect2, varscan2
- TUBB1 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99414046; called by muse, mutect2, varscan2
- TUBB4A | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99899965; called by muse, mutect2, varscan2
- UBA6 | c.396C>G p.Y132* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100451682; called by muse, mutect2, varscan2
- UHMK1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.009); catalogued as COSV56421641; called by muse, mutect2, varscan2
- UIMC1 | c.350G>T p.S117I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101022131; called by muse, mutect2, varscan2
- ULK4 | c.3322C>T p.L1108F | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100092277; called by muse, mutect2
- UNC5C | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324353084, COSV101497884; called by muse, mutect2
- USP10 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs538632016, COSV54751951; called by muse, mutect2, varscan2
- USP19 | c.3064G>A p.V1022I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.154); catalogued as rs368479180; called by muse, mutect2, varscan2
- USP29 | c.1586T>C p.V529A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99518045; called by muse, mutect2, varscan2
- USP53 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.3); catalogued as rs755943510, COSV99917683; called by muse, mutect2, varscan2
- USP7 | c.304A>C p.M102L | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV100784171; called by muse, mutect2, varscan2
- VASP | c.910+1G>A p.X304_splice | Splice Site (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99840967; called by muse, mutect2, varscan2
- VKORC1L1 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100663160; called by muse, mutect2, varscan2
- VPS13A | c.5347G>A p.E1783K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100652650; called by muse, varscan2
- VPS16 | c.1879C>G p.Q627E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100988452; called by muse, mutect2, varscan2
- VPS18 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as rs1254884497, COSV55029219, COSV55029450; called by muse, mutect2, varscan2
- VPS41 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99730867; called by muse, mutect2, varscan2
- VWF | c.4976G>A p.R1659Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.242); catalogued as rs781675955, COSV99778903; called by muse, mutect2, varscan2
- WASHC4 | c.1384A>G p.M462V | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100162415; called by muse, mutect2, varscan2
- WDR1 | c.1319G>A p.S440N (on ENST00000382452; = p.S300N on NM_005112.5) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101221111; called by muse, mutect2, varscan2
- WDR36 | c.1943C>A p.T648N | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101550965; called by muse, mutect2, varscan2
- WDR6 | c.2421del p.R808Gfs*33 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs750038548, COSV58247104; called by mutect2, pindel, varscan2
- WDR91 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs752551859, COSV100615681; called by muse, mutect2, varscan2
- WDTC1 | c.1594G>A p.G532S (on ENST00000319394 / NM_001276252.2; = p.G531S on NM_015023.5) | Missense Mutation (SNP) | VAF 82/308 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1171296628, COSV100088822; called by muse, mutect2, varscan2
- WIPF2 | c.1288C>A p.R430S | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100063525, COSV100063743; called by muse, varscan2
- XAF1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567884801, COSV100695043; called by muse, mutect2, varscan2
- XG | c.158A>T p.Y53F | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.022); catalogued as COSV101150791; called by muse, mutect2, varscan2
- XPO4 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 47/197 reads (24%) | catalogued as COSV99688517; called by muse, mutect2, varscan2
- XYLT1 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358328447, COSV99761589; called by muse, mutect2, varscan2
- YIPF3 | c.428T>A p.V143D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58307462; called by muse, mutect2, varscan2
- YLPM1 | c.6220G>A p.A2074T | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV100353838; called by muse, mutect2, varscan2
- YTHDC1 | c.1224A>T p.K408N (on ENST00000344157 / NM_001031732.4; = p.K390N on NM_133370.4) | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100704695; called by muse, mutect2, varscan2
- ZBBX | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV100283886; called by muse, mutect2, varscan2
- ZBTB33 | c.1501A>G p.R501G | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100434162; called by muse, mutect2, varscan2
- ZBTB46 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs746744472, COSV55507986; called by muse, mutect2, varscan2
- ZC3H12B | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs776433255, COSV59052219; called by muse, mutect2, varscan2
- ZCCHC14 | c.1309G>A p.D437N (on ENST00000268616; = p.D574N on NM_015144.3) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs1567508449, COSV99233862; called by muse, mutect2, varscan2
- ZDHHC18 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765667318, COSV65145479; called by muse, mutect2, varscan2
- ZDHHC19 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs770352847, COSV56348237; called by muse, mutect2, varscan2
- ZDHHC20 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100203433; called by muse, mutect2, varscan2
- ZDHHC3 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368475280; called by muse, mutect2, varscan2
- ZEB2 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100355939, COSV57951666; called by muse, mutect2, varscan2
- ZMYM2 | c.3622G>T p.G1208* | Nonsense Mutation (SNP) | VAF 21/153 reads (14%) | catalogued as COSV101243706; called by muse, mutect2, varscan2
- ZMYND8 | c.2642C>T p.T881M (on ENST00000311275 / NM_001363741.2; = p.T855M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs373435522, COSV53683773; called by muse, mutect2, varscan2
- ZNF256 | c.1484A>G p.E495G | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV99990793; called by muse, mutect2, varscan2
- ZNF34 | c.1513T>C p.C505R | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603280; called by muse, mutect2, varscan2
- ZNF365 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV101237957, COSV67925412; called by muse, mutect2, varscan2
- ZNF385A | c.736C>T p.P246S (on ENST00000338010 / NM_001130967.3; = p.P226S on NM_015481.3) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.281); catalogued as rs1356292273, COSV100566829; called by muse, mutect2, varscan2
- ZNF408 | c.1693_1694del p.T565Afs*67 | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | catalogued as rs1274593315; called by pindel, varscan2
- ZNF423 | c.3558G>T p.E1186D (on ENST00000563137 / NM_001379286.1; = p.E1178D on NM_015069.4) | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.182); catalogued as COSV99281428; called by muse, mutect2, varscan2
- ZNF43 | c.1361A>G p.Y454C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100731801; called by muse, mutect2, varscan2
- ZNF486 | c.377G>C p.C126S | Missense Mutation (SNP) | VAF 52/374 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV100631243, COSV58721462; called by muse, mutect2, varscan2
- ZNF496 | c.254T>G p.L85R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665601; called by muse, mutect2, varscan2
- ZNF557 | c.1185dup p.P396Tfs*3 (on ENST00000414706 / NM_001044388.2; = p.P403Tfs*3 on NM_024341.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 22/146 reads (15%) | catalogued as rs759839287; called by mutect2, varscan2
- ZNF57 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV100182889, COSV60982824; called by muse, mutect2, varscan2
- ZNF586 | c.1004A>G p.H335R | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101197679; called by muse, mutect2, varscan2
- ZNF697 | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.068); catalogued as COSV70284372; called by muse, mutect2, varscan2
- ZNF74 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs773380844, COSV62624498; called by muse, mutect2, varscan2
- ZNF765 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV101125460; called by muse, mutect2, varscan2
- ZNF786 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs776244491, COSV100302826; called by muse, mutect2, varscan2
- ZNF831 | c.153del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs750329558; called by mutect2, varscan2
- ZNF91 | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV100322636; called by muse, mutect2, varscan2
- ZSCAN5B | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs368972539; called by muse, varscan2
- ACSS2 | c.1394_1396del p.F465del | In Frame Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- ADAM29 | c.717dup p.G240Wfs*3 | Frame Shift Ins (INS) | VAF 37/163 reads (23%) | called by mutect2, pindel, varscan2
- AK5 | c.194_196del p.K65del (on ENST00000354567 / NM_174858.3; = p.K39del on NM_012093.4) | In Frame Del (DEL) | VAF 50/251 reads (20%) | called by pindel, varscan2
- AKAP13 | c.3588dup p.T1197Hfs*9 | Frame Shift Ins (INS) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- ANGPTL5 | c.873del p.E292Kfs*30 | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.4577dup p.N1526Kfs*7 | Frame Shift Ins (INS) | VAF 24/135 reads (18%) | called by mutect2, varscan2
- ARAF | c.763del p.R255Gfs*37 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- ARID1A | c.4703del p.P1568Lfs*44 | Frame Shift Del (DEL) | VAF 57/475 reads (12%) | called by mutect2, pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | called by mutect2, pindel, varscan2
- ASB18 | c.1336del p.L446Cfs*? | Frame Shift Del (DEL) | VAF 19/147 reads (13%) | called by mutect2, pindel, varscan2
- AXIN1 | c.234del p.T79Pfs*5 | Frame Shift Del (DEL) | VAF 23/52 reads (44%) | called by mutect2, pindel, varscan2
- AXIN2 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2
- BAG3 | c.412_413del p.L138Afs*11 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by pindel, varscan2
- BAIAP2L2 | c.1223_1224insAACACCCAT p.P407_M408insITP | In Frame Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, pindel
- BCL9L | c.689del p.G230Afs*62 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- BPHL | c.342dup p.E115* | Frame Shift Ins (INS) | VAF 21/110 reads (19%) | called by mutect2, pindel, varscan2
- BRD2 | c.113_116del p.L38Rfs*47 | Frame Shift Del (DEL) | VAF 24/105 reads (23%) | called by mutect2, pindel, varscan2
- CALM2 | c.52del p.S18Hfs*11 | Frame Shift Del (DEL) | VAF 88/445 reads (20%) | called by mutect2, pindel, varscan2
- CAMSAP3 | c.21del p.P11Rfs*7 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel
- CASD1 | c.2347del p.C783Vfs*21 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- CASK | c.2270del p.N757Tfs*40 (on ENST00000378163 / NM_001367721.1; = p.N752Tfs*40 on NM_003688.3) | Frame Shift Del (DEL) | VAF 22/141 reads (16%) | called by mutect2, pindel, varscan2
- CASKIN2 | c.2919_2920del p.E973Dfs*18 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- CCDC189 | c.526del p.C176Afs*51 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | called by mutect2, pindel, varscan2
- CD44 | c.1686_1687del p.H563Lfs*17 | Frame Shift Del (DEL) | VAF 52/244 reads (21%) | called by pindel, varscan2
- CDH4 | c.2583del p.Y862Mfs*22 | Frame Shift Del (DEL) | VAF 24/129 reads (19%) | called by mutect2, pindel, varscan2
- CELSR3 | c.7585dup p.R2529Pfs*2 | Frame Shift Ins (INS) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- CFAP299 | c.675del p.F225Lfs*21 | Frame Shift Del (DEL) | VAF 21/151 reads (14%) | called by mutect2, pindel, varscan2
- CFAP65 | c.1896del p.M633* | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- COL5A1 | c.3514del p.D1172Tfs*104 | Frame Shift Del (DEL) | VAF 28/155 reads (18%) | called by mutect2, pindel, varscan2
- CST7 | c.68dup p.D24Rfs*8 | Frame Shift Ins (INS) | VAF 16/100 reads (16%) | called by mutect2, pindel, varscan2
- CYLC2 | c.630del p.G211Efs*22 | Frame Shift Del (DEL) | VAF 109/640 reads (17%) | called by mutect2, pindel, varscan2
- DAG1 | c.1256del p.P419Lfs*88 | Frame Shift Del (DEL) | VAF 131/564 reads (23%) | called by mutect2, pindel, varscan2
- DDO | c.866_867del p.E289Afs*58 (on ENST00000368924 / NM_001368172.1; = p.E230Afs*58 on NM_004032.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | called by pindel, varscan2
- DDX60 | c.3580del p.T1194Pfs*8 | Frame Shift Del (DEL) | VAF 26/139 reads (19%) | called by mutect2, varscan2
- DIP2B | c.2760_2761del p.F921Sfs*62 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | called by pindel, varscan2
- DOCK1 | c.2910_2912del p.I970del | In Frame Del (DEL) | VAF 16/67 reads (24%) | called by pindel, varscan2
- DOCK4 | c.3975del p.K1325Nfs*6 | Frame Shift Del (DEL) | VAF 26/187 reads (14%) | called by mutect2, pindel, varscan2
- EFCAB5 | c.2251del p.I751* | Frame Shift Del (DEL) | VAF 28/183 reads (15%) | called by mutect2, varscan2
- ELFN2 | c.1976del p.G659Afs*41 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel
- ENTPD2 | c.611del p.G204Vfs*171 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | called by mutect2, pindel
- EOMES | c.995del p.G332Afs*4 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- EPHA5 | c.242dup p.N81Kfs*8 | Frame Shift Ins (INS) | VAF 64/265 reads (24%) | called by mutect2, pindel, varscan2
- ERAP1 | c.1750del p.T584Qfs*21 | Frame Shift Del (DEL) | VAF 24/132 reads (18%) | called by mutect2, pindel, varscan2
- FAM3A | c.386-3del | Splice Region (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- FBRS | c.722del p.P241Lfs*63 (on ENST00000287468; = p.P761Lfs*63 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel
- FBXO21 | c.1736_1737del p.H579Pfs*2 (on ENST00000330622 / NM_033624.3; = p.H572Pfs*2 on NM_015002.3) | Frame Shift Del (DEL) | VAF 40/193 reads (21%) | called by pindel, varscan2
- FCGBP | c.1598_1599del p.V533Afs*13 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by pindel, varscan2
- FCHSD1 | c.1832del p.P611Qfs*52 | Frame Shift Del (DEL) | VAF 28/146 reads (19%) | called by mutect2, pindel, varscan2
- FER | c.1428del p.K476Nfs*53 | Frame Shift Del (DEL) | VAF 44/208 reads (21%) | called by mutect2, pindel, varscan2
- FLNC | c.3240del p.A1081Rfs*17 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- FOXI1 | c.312del p.S105Afs*14 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- GDAP2 | c.165del p.V56Wfs*11 | Frame Shift Del (DEL) | VAF 43/225 reads (19%) | called by mutect2, pindel, varscan2
- GSPT2 | c.1692del p.K564Nfs*13 | Frame Shift Del (DEL) | VAF 36/196 reads (18%) | called by mutect2, pindel, varscan2
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 62/288 reads (22%) | called by mutect2, pindel, varscan2
- HUNK | c.2025_2030dup p.H676_Q677insHH | In Frame Ins (INS) | VAF 5/37 reads (14%) | called by mutect2, pindel
- ILDR2 | c.470del p.N157Mfs*117 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- IQCE | c.1609-5_1609delinsCCAG p.X537_splice | Splice Site (DEL) | VAF 8/73 reads (11%) | called by pindel, varscan2*
- JARID2 | c.3216del p.E1073Kfs*106 | Frame Shift Del (DEL) | VAF 35/229 reads (15%) | called by mutect2, pindel, varscan2
- KANSL1L | c.2496dup p.Y833Ifs*2 | Frame Shift Ins (INS) | VAF 41/246 reads (17%) | called by mutect2, pindel, varscan2
- KANSL1L | c.1186del p.I396Sfs*4 | Frame Shift Del (DEL) | VAF 42/261 reads (16%) | called by mutect2, pindel, varscan2
- KCNQ4 | c.283del p.R95Afs*44 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- KIF21A | c.1299_1301del p.N434del | In Frame Del (DEL) | VAF 48/224 reads (21%) | called by pindel, varscan2
- KRT222 | c.121del p.M41Wfs*8 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- LATS1 | c.3117del p.F1039Lfs*19 | Frame Shift Del (DEL) | VAF 39/220 reads (18%) | called by mutect2, pindel, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, varscan2
- MASTL | c.1173del p.K391Nfs*12 | Frame Shift Del (DEL) | VAF 28/125 reads (22%) | called by mutect2, pindel, varscan2
309 further variants in this file (59 protein-altering or splice-affecting, 231 silent, 19 other) are not listed here.
